Gene-level copy-number profile of tumor specimen TCGA-44-3918-01B from TCGA case TCGA-44-3918, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.9 years (22,236 days).
Specimen TCGA-44-3918-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.089f9936-ae7f-4aef-b94f-1b968f1d311f.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-3918-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate.
https://portal.gdc.cancer.gov/files/0ebf5e23-fe2a-4800-a0ee-d47532f0c8d1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 559; copy number 2: 59,569; copy number 3: 132; copy number 4: 3; copy number 5: 7.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-3918-01A-01D-A273-01): tumor purity 0.45, ploidy 1.8, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:123,135,970–123,150,672, 2 genes: HMX3, HMX2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,537,184–68,712,498, 6 genes, copy number 5: UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15, AC147055.1.
- chr18:74,409,415–74,413,209, 1 gene, copy number 5: LINC01922.

Autosomal genes at a single copy (total copy number 1): 38. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
